Somatic mutation profile of cancer-model specimen HCM-CSHL-0463-C50-85A (3D Organoid; aliquot HCM-CSHL-0463-C50-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0463-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 59.0 years (21,535 days).
Specimen HCM-CSHL-0463-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b90901aa-49a5-49d9-9a65-f484ba28268d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0463-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0463-C50-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf5e6a0-dc52-4ee1-97c9-6be0a7062449

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BDH2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as rs199621816; called by muse, mutect2, varscan2
- GALNT3 | c.904del p.V302* | Frame Shift Del (DEL) | VAF 154/411 reads (37%) | catalogued as COSV101205035; called by mutect2, pindel, varscan2
- PDE3B | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565169364; called by muse, mutect2
- TMPRSS3 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746713644, COSV52308306; called by muse, mutect2, varscan2
- USP24 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1172713544, COSV53767630; called by muse, mutect2, varscan2
- ZBED5 | c.961T>C p.F321L | Missense Mutation (SNP) | VAF 133/327 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs748700359; called by muse, mutect2, varscan2
- ATM | c.1465T>G p.C489G | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRM1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPR2 | c.7256A>G p.D2419G | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PTBP2 | c.473T>C p.L158P (on ENST00000426398 / NM_001300986.2; = p.L150P on NM_021190.4) | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF213 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 242/554 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM266 | c.271del p.W91Gfs*15 | Frame Shift Del (DEL) | VAF 194/509 reads (38%) | called by mutect2, pindel, varscan2
- XKR4 | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADGRA1 | c.798C>A p.G266= | Silent (SNP) | VAF 79/632 reads (13%) | called by muse, mutect2, varscan2
- KCND3 | c.1950C>G p.V650= | Silent (SNP) | VAF 127/309 reads (41%) | called by muse, mutect2, varscan2
- OTOG | c.987C>T p.S329= | Silent (SNP) | VAF 142/565 reads (25%) | catalogued as rs1009931498; called by muse, mutect2
- BLOC1S6 | c.82+271G>C | Intron (SNP) | VAF 97/234 reads (41%) | called by muse, mutect2, varscan2
- SYNE3 | c.790-47A>G | Intron (SNP) | VAF 93/488 reads (19%) | catalogued as rs1262889706; called by muse, mutect2, varscan2
